TCGA case TCGA-P3-A5Q6 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: Fred Hutchinson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/451e4916-80ee-45f8-ad70-84340868a5a9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 480 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.1 years (17,917 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 480 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Gross Extension; Lymph nodes positive: 4; Lymph nodes tested: 35; Margin status: Involved; Perineural invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab + Cisplatin; Days to treatment start: 43 days; Days to treatment end: 104 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 98 days; Treatment dose: 4,000 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 98 days; Treatment dose: 5,000 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment intent type: Cure; Days to treatment end: 104 days; Treatment outcome: Persistent Disease.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 49.8 years (18,197 days); Days to diagnosis: 280 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Pharynx, NOS. Age at diagnosis: 50.1 years (18,289 days); Days to diagnosis: 372 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 280 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 280 days; Evidence of progression type: Convincing Image Source.
- Day 372 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pharynx, NOS; Days to recurrence: 372 days (1.0 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 480 days (1.3 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-P3-A5Q6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 10 mg.
  Slide TCGA-P3-A5Q6-01A-01-TS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 48; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 3.
- Sample TCGA-P3-A5Q6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-P3-A5Q6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Positive; Tobacco smoking history indicator: 4; Alcohol history documented: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Definitive treatment evidence disease after: Yes; Cause of death: Related to Head & Neck Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 480 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 480 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 280 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-P3-A5Q6-01A-11D-A28Q-01): tumor purity 0.46, ploidy 2.74, whole-genome doublings 1.
